TCGA case TCGA-WC-A87Y — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3a161c85-2544-4283-a10d-e332c9dd1692

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 59 years; Vital status: Dead; Days to death: 1,314 days (3.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Mixed epithelioid and spindle cell melanoma: ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.9 years (21,865 days); Year of diagnosis: 2011; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIA; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,314 days (3.6 years); Sites of involvement: Eye, Choroid.
   Pathology details: Consistent pathology review: Yes; Epithelioid cell percent range: 1-30%; Extrascleral extension present: Yes; Measurement type: Pathologic; Spindle cell percent range: 61-90%; Tumor depth measurement: 7; Tumor shape: Dome.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 13.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 22 days; Days to treatment end: 64 days; Treatment dose: 60 Gy; Treatment outcome: Stable Disease; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 369 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 1,314 days (3.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 955.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 96.4 kg; Height: 177 cm; BMI: 30.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WC-A87Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 20 mg.
  Slide TCGA-WC-A87Y-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-WC-A87Y-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WC-A87Y-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Spindle Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: 1-30%.
- Primary pathology, Gene expression profile list: Gene expression profile: Class 2.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness: 7 mm; Tumor thickness measurement: Pathologic Measurement.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Cause of death: Metastatic Uveal Melanoma; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,314 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,314 days; progression-free interval: no event (censored), 1,314 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WC-A87Y-01A-11D-A39V-01): tumor purity 0.7, ploidy 2, whole-genome doublings 0.
